Gene-level copy-number profile of tumor specimen TCGA-55-8092-01A from TCGA case TCGA-55-8092, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 75.6 years (27,597 days).
Specimen TCGA-55-8092-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5c79b823-af1a-4fa9-9cbb-1f1224d852c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8092-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/70be475b-b16e-47b7-88fe-566f2254dd24

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,101; copy number 2: 13,503; copy number 3: 21,146; copy number 4: 17,470; copy number 5: 3,913; copy number 6: 2,005; copy number 7: 103; copy number 8: 352; copy number 9: 212.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8092-01A-11D-2237-01): tumor purity 0.38, ploidy 3.24, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 667 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:57,352,999–61,153,962, 28 genes, copy number 8: RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271.
- chr4:61,211,652–61,428,221, 2 genes, copy number 8: RPL17P19, AC020741.1.
- chr7:70,972–23,897,335, 386 genes, copy number 7–9 (broad region; genes not listed).
- chr7:77,122,434–77,329,533, 1 gene, copy number 7 (within-gene range 6–7): CCDC146.
- chr7:77,246,340–80,312,456, 35 genes, copy number 7 (within-gene range 4–7): AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA, AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1.
- chr14:83,805,496–87,872,291, 29 genes, copy number 7: AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1, LINC02296, AL135746.1, LINC02330, AL359237.1, AL136501.1.
- chr22:18,150,170–21,517,533, 186 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
